CCDI case PBCCEP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/89a19409-8294-4276-83d4-85c233834e41

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Epithelial-myoepithelial carcinoma: ICD-O-3 morphology code: 8562/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 3.0 years (1,109 days).

Biospecimens (2 samples)
- Sample 0DOG2W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOG3G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
